TCGA case TCGA-A6-2676 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/89a6384e-1cea-440b-9f17-d57cb0805174

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 75 years; Vital status: Dead; Days to death: 1,305 days (3.6 years).

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.9; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Cecum; Classification of tumor: primary; Age at diagnosis: 75.0 years (27,403 days); Year of diagnosis: 2009; AJCC staging edition: 6th; AJCC pathologic T: T4; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,305 days (3.6 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 15; Lymphatic invasion present: No; Non nodal tumor deposits: No; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Treatment intent type: Adjuvant; Days to treatment start: 76 days; Days to treatment end: 113 days; Number of cycles: 3; Treatment dose: 9,485 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Treatment intent type: Adjuvant; Days to treatment start: 76 days; Days to treatment end: 111 days; Number of cycles: 3; Treatment dose: 1,581 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Leucovorin; Treatment intent type: Adjuvant; Days to treatment start: 76 days; Days to treatment end: 111 days; Number of cycles: 3; Treatment dose: 1,750 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Treatment intent type: Adjuvant; Days to treatment start: 76 days; Days to treatment end: 111 days; Number of cycles: 3; Treatment dose: 360 mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 447 days (1.2 years); Disease response: Tumor Free.
- Days to follow up: 711 days (1.9 years); Disease response: Tumor Free.
- Days to follow up: 1,305 days (3.6 years); Disease response: Tumor Free.

Molecular and laboratory tests
- CEA: 6.3 ng/mL.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 45.9 kg; Height: 154.9 cm; BMI: 19.1.

Family history
- Relative with cancer history: no.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-A6-2676-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.9; Intermediate dimension: 0.8; Shortest dimension: 0.4.
  Slide TCGA-A6-2676-01A-01-BS1: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 5.
  Slide TCGA-A6-2676-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 90; Percent normal cells: 5; Percent necrosis: 3; Percent stromal cells: 7.
- Sample TCGA-A6-2676-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-A6-2676-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-A6-2676-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 2; Intermediate dimension: 0.9; Shortest dimension: 0.7.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Anatomic organ subdivision: Cecum; Lymph nodes examined: Yes; CEA level pretreatment: 6.3; Lymphovascular invasion indicator: No; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: No; Colon polyps at procurement indicator: No.
- Drug treatment 1: Regimen number: 1; Pharmaceutical therapy drug name: 5- FU.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 1; Pharmaceutical therapy drug name: 5-FU.
- Follow-up form 1: Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Follow-up form 3: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,305 days; disease-specific survival: no event (censored), 1,305 days; disease-free interval: no event (censored), 1,305 days; progression-free interval: no event (censored), 1,305 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-A6-2676-01): tumor purity 0.69, ploidy 2.03, whole-genome doublings 0 (call status: legacy_call).
